CPTAC case C3L-05302 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c31d703c-1fc4-444c-8eeb-b36f3b3a925c

Demographics
Sex at birth: male; Race: white; Year of birth: 1946; Vital status: Dead; Days to death: 938 days (2.6 years); Year of death: 2021; Country of birth: Serbia.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 72.7 years (26,559 days); Year of diagnosis: 2019; AJCC staging edition: 8th; AJCC clinical M: MX; AJCC pathologic T: T4a; AJCC pathologic N: N3; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 938 days (2.6 years); Progression or recurrence: yes; Days to recurrence: 130 days; Days to last follow up: 938 days (2.6 years); Clark level: V; Tumor focality: Unifocal; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >4.0 mm; Greatest tumor dimension: 2.7 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 15; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: No; Vascular invasion present: Yes.

Follow-up (3 entries)
- Days to follow up: 292 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 606 days (1.7 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 938 days (2.6 years); Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-05302-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 237 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-05302-21: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-05302-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 342 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-05302-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -7 days; Method of sample procurement: Blood Draw.
